CCDI case PBCMAM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/18cefb9c-904d-45b2-b077-c726f87aba17

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 20.4 years (7,435 days).

Biospecimens (3 samples)
- Sample 0DV5RQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV5S3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV5SD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
